Gene-level copy-number profile of tumor specimen TARGET-10-PASNTZ-09A from TARGET case TARGET-10-PASNTZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,627 days).
Specimen TARGET-10-PASNTZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.981cb0ce-f301-55fa-ac4f-ad97e5117601.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASNTZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 355 have no estimate.
https://portal.gdc.cancer.gov/files/4dee444d-8d05-41cf-a783-f723e7dce7ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,347; copy number 1: 70; copy number 2: 57,734; copy number 3: 111; copy number 4: 4; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr5:153,755,382–153,755,680, 1 gene: RN7SL177P.
- chr6:30,516,266–30,563,723, 3 genes: LINC02569, GNL1, PRR3.
- chr8:39,314,591–39,522,852, 2 genes (within-gene range 0–2): ADAM5, ADAM3A.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:59,262,680–59,263,391, 1 gene, copy number 5: RPP40P2.
- chr16:78,890,231–78,892,302, 1 gene, copy number 5: AC027279.4.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
